Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FN, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FN-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative lobular carcinoma

Date of Procurement: Anatomic Site: Right breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: OCT

Container: block Type of Procurement: surgery Grade: 2

T Stage: 1 N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement:

ICD-0-3

CQCF: carcinoma, infiltrating ductal, NOS 8500/3
Path: carcinoma, infiltrating lobular, NOS 8520/3
Site: breast, NOS C50.9 lw
10/21/11

Path report shows tumor as lobular and CQCF states
TCGA tumor is ductal. After email confirmation with
TSS, TSS pathologist confirms histology of TCGA tumor
to be ductal. 10/26/11
h

Source: NCI Genomic Data Commons file b6c5ab4f-cf9e-42f5-a7d2-8b997b0a4087 (TCGA-AN-A0FN.6B53F577-5EB6-4AF5-9773-3654D3432BE4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).